Gene-level copy-number profile of tumor specimen HTMCP-03-06-02040-01B from CGCI case HTMCP-03-06-02040, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 65.1 years (23,795 days).
Specimen HTMCP-03-06-02040-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 96231532-838f-434b-a39d-0dcb79ead8ef.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02040-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/1f72272c-7fe1-4b07-8077-3083ddd967b7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 317; copy number 2: 10,469; copy number 3: 26,062; copy number 4: 15,831; copy number 5: 3,724; copy number 6: 991; copy number 7: 276; copy number 9: 25; copy number 10: 514; copy number 11: 105; copy number 12: 54; copy number 15: 5; copy number 18: 2; copy number 24: 7; copy number 26: 3; copy number 27: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr1:149,676,851–149,747,818, 2 genes (within-gene range 0–3): AC243772.3, RNU1-68P.
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr2:132,037,787–132,037,993, 1 gene: AC093787.1.
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 992 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–693,352, 27 genes, copy number 10: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1.
- chr5:767,382–45,895,970, 651 genes, copy number 9–12 (broad region; genes not listed).
- chr6:30,720,352–30,744,548, 6 genes, copy number 7: TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3.
- chr9:4,984,390–6,066,714, 36 genes, copy number 9–27: JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1.
- chr9:98,069,275–98,255,649, 6 genes, copy number 7 (within-gene range 5–7): TRIM14, Metazoa_SRP, CORO2A, TBC1D2, MIR6854, AL360081.1.
- chr9:104,927,553–105,439,171, 5 genes, copy number 7 (within-gene range 5–7): AL359182.1, CT70, AL591506.1, RN7SKP191, SLC44A1.
- chr9:137,204,082–137,423,211, 17 genes, copy number 7 (within-gene range 5–7): TMEM203, NDOR1, RNF208, CYSRT1, RNF224, SLC34A3, TUBB4B, FAM166A, STPG3-AS1, STPG3, NELFB, TOR4A, BX255925.2, BX255925.1, BX255925.4, NRARP, EXD3.
- chr12:6,155,035–9,995,694, 219 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr12:25,195,216–25,250,936, 4 genes, copy number 7: ETFRF1, KRAS, AC092794.1, AC092794.2.
- chr12:26,971,579–27,014,434, 1 gene, copy number 7 (within-gene range 6–7): TM7SF3.
- chr12:27,022,546–27,161,393, 6 genes, copy number 7: MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2.
- chr13:74,434,538–74,555,515, 1 gene, copy number 10 (within-gene range 4–10): AL355390.2.
- chr20:34,347,671–34,560,345, 12 genes, copy number 7: AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1, DYNLRB1, Y_RNA, MAP1LC3A.
- chr21:44,133,610–44,210,114, 1 gene, copy number 26 (within-gene range 2–26): GATD3A.

Autosomal genes at a single copy (total copy number 1): 253. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
